Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4973, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4973-01A (Primary Tumor).

[page 1 of 3]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA - BP - 4973

Clinical Diagnosis & History:

Right renal mass/renal vein thrombus.

Specimens Submitted:

- 1: Right kidney and paracaval lymph nodes , Nephrectomy
- 2: Falciform ligament , Excision

DIAGNOSIS:

1. Right kidney and paracaval lymph nodes , Nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 9 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Chronic interstitial inflammation

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

2. Falciform ligament , Excision:

Benign fibro-adipose tissue, no tumor seen.

[page 2 of 3]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh for frozen section consultation labeled "right kidney and paracaval lymph nodes" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 514 g in total. The kidney measures 24 x 10.6 x 4.5 cm. The attached ureter measures 12 cm in length and 0.3 cm in diameter. The attached renal vein measures 0.8 cm in length and 1.4 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified measuring 6 x 1.5 x 1 cm. The kidney is inked black and bivalved to reveal a yellow - orange lobulated mass with focal areas of hemorrhage measuring 9 x 8.6 x 4 cm, located in upper pole. The tumor appears to involve the renal capsule however does not reach the inked margins of resection. It grossly involves the renal vein. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 1.2 cm and the calyces appear normal. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

FSC - frozen section control
UVM -- ureteral and vessel margins
RVT-tumor with renal vein
T-- tumor
TC-- tumor with capsule
HF-- hilar fat
TSF -- tumor with sinus fat
RP -- renal pelvis representative sections
N -- representative sections kidney
A -- adrenal gland

2). The specimen is received in formalin labeled "falciform ligament". It consists of a fatty soft tissue piece measuring 10 x 6.5 x 3 cm. It is serially sectioned to reveal unremarkable cut surfaces. Representative sections are submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: Right kidney and paracaval lymph nodes , Nephrectomy

Block	Sect. Site	PCs
1	a	1
1	fsc	1
1	hf	1
1	n	1
1	rp	1
1	rvt	2
4	t	4
2	tc	2
2	tsf	2
1	uvm	3

Part 2: Falciform ligament , Excision

Block	Sect. Site	PCs
2	U	2

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS RENAL CELL CARCINOMA, CLEAR CELL TYPE [REDACTED]
PERMANENT DIAGNOSIS: Same
- [REDACTED]

Source: NCI Genomic Data Commons file 136cf937-aaaa-453f-8f82-72eef88e38e1 (TCGA-BP-4973.F80C8421-2A2B-4310-8E2E-225D724B9C7D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).